Gene-level copy-number profile of tumor specimen ALCH-B53M-TTP1-A from ALCHEMIST case ALCH-B53M, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 70.5 years (25,740 days).
Specimen ALCH-B53M-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 6c5152b1-5314-4cc2-9d86-cf5a8c3e5ec3.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B53M-NB2-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,711 have no estimate.
https://portal.gdc.cancer.gov/files/38bc6136-4e37-4a07-8a16-9cb2dd6c0c22

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 96; copy number 1: 6,401; copy number 2: 51,780; copy number 3: 625; copy number 4: 3; copy number 5: 2; copy number 6: 2; copy number 7: 2; copy number 11: 1.

Homozygous deletions (total copy number 0; autosomes only): 71 genes in 24 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:1,917,590–1,919,279, 1 gene: TMEM52.
- chr1:212,466,699–212,472,905, 1 gene: LINC02771.
- chr2:10,767,875–10,770,058, 1 gene (within-gene range 0–2): AC092687.3.
- chr2:201,288,271–201,357,398, 1 gene: FLACC1.
- chr3:138,825,063–138,889,957, 2 genes (within-gene range 0–2): EEF1A1P25, ATP5MC1P3.
- chr4:10,074,339–10,116,949, 3 genes (within-gene range 0–2): WDR1, MIR3138, RNA5SP155.
- chr7:63,044,827–63,060,084, 2 genes: AC069285.2, AC069285.3.
- chr7:99,374,249–99,419,616, 3 genes (within-gene range 0–2): ARPC1B, PDAP1, BUD31.
- chr8:11,576,257–11,582,817, 1 gene: LINC00208.
- chr8:27,633,868–27,676,776, 1 gene: SCARA3.
- chr9:33,441,156–33,473,930, 4 genes: AQP3, AL356218.1, NOL6, MIR6851.
- chr11:2,173,063–2,173,138, 1 gene: MIR4686.
- chr12:109,850,945–109,880,541, 3 genes: GLTP, AC007834.2, RN7SL441P.
- chr12:111,405,923–111,451,623, 1 gene: SH2B3.
- chr14:24,052,009–24,069,729, 1 gene: CARMIL3.
- chr14:90,820,064–90,828,199, 1 gene: LINC02321.
- chr14:93,138,066–93,138,465, 1 gene: CYB5AP3.
- chr14:103,529,196–103,714,249, 10 genes (within-gene range 0–2): TRMT61A, RNU7-160P, AL139300.2, BAG5, KLC1, COA8, AL139300.1, RNU4-68P, AL049840.2, AL049840.6.
- chr14:103,696,353–103,697,163, 1 gene (within-gene range 0–2): AL049840.5.
- chr15:25,180,497–25,215,622, 20 genes (within-gene range 0–2): SNORD115-6, SNORD115-7, SNORD115-8, SNORD115-9, SNORD115-10, SNORD115-11, SNORD115-12, SNORD115-13, SNORD115-14, SNORD115-15, SNORD115-16, SNORD115-17, SNORD115-18, SNORD115-19, SNORD115-20, SNORD115-21, SNORD115-22, SNORD115-23, SNORD115-24, SNORD115-25.
- chr16:11,668,455–11,679,152, 1 gene (within-gene range 0–3): SNN.
- chr16:27,447,669–27,453,393, 1 gene (within-gene range 0–2): IL21R-AS1.
- chr17:2,689,386–3,037,741, 9 genes (within-gene range 0–2): CLUH, MIR6776, AC005696.1, AC005696.4, CCDC92B, MIR1253, hsa-mir-1253, RAP1GAP2, AC015921.1.
- chr17:75,525,080–75,575,209, 1 gene: LLGL2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 7 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr19:1,259,384–1,274,880, 2 genes, copy number 6: CIRBP, CIRBP-AS1.
- chr21:43,414,483–43,427,131, 1 gene, copy number 11: SIK1.
- chr21:43,461,960–43,479,534, 2 genes, copy number 5 (within-gene range 5–6): LINC00313, AP001048.1.
- chr22:21,341,595–21,358,067, 2 genes, copy number 7: PPP1R26P5, LINC01651.

Autosomal genes at a single copy (total copy number 1): 3,570. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
